Somatic mutation profile of tumor specimen TCGA-WY-A85C-01A (aliquot TCGA-WY-A85C-01A-11D-A36O-08) from TCGA case TCGA-WY-A85C, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 37.0 years (13,506 days).
Specimen TCGA-WY-A85C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fd0563f-92dd-452f-a3b3-65f099943b49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WY-A85C-10A (Blood Derived Normal), aliquot TCGA-WY-A85C-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfdf116d-2543-4c57-b1e6-9144df1134dd

The open-access MAF lists 28 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Nonsense Mutation 5, Silent 4, Frame Shift Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 58/121 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CHD4 | c.4783G>A p.V1595I (on ENST00000357008 / NM_001363606.2; = p.V1608I on NM_001273.5) | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs201992075, COSV100539020; ClinVar: benign; called by muse, mutect2, varscan2
- COL24A1 | c.410T>A p.L137* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV100993913; called by muse, mutect2, varscan2
- DDX4 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV100737741; called by muse, mutect2, varscan2
- EFNB2 | c.224A>C p.Y75S | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99808928; called by muse, mutect2
- GPRC6A | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59956335; called by muse, mutect2, varscan2
- HECTD4 | c.12472C>T p.Q4158* | Nonsense Mutation (SNP) | VAF 69/161 reads (43%) | catalogued as COSV101108322; called by muse, mutect2, varscan2
- LRRC52 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs762655638, COSV54232866; called by muse, mutect2, varscan2
- MGARP | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101299235; called by muse, mutect2
- MTUS2 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV101462346; called by muse, mutect2, varscan2
- MYH13 | c.4913G>A p.R1638H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1567655857, COSV52848279; called by muse, mutect2, varscan2
- OR10A4 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as COSV101139583; called by muse, mutect2
- OR2A12 | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV101283198; called by muse, mutect2
- POGLUT1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 40/59 reads (68%) | catalogued as rs140695299, CM140065, COSV99809796; called by muse, mutect2, varscan2
- ROS1 | c.4536C>G p.D1512E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100877638; called by muse, mutect2, varscan2
- SNX25 | c.1641G>A p.W547* | Nonsense Mutation (SNP) | VAF 63/170 reads (37%) | catalogued as COSV99253370; called by muse, mutect2, varscan2
- TBX22 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 76/90 reads (84%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100960929; called by muse, mutect2, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 29/70 reads (41%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- TTBK2 | c.3324C>G p.F1108L | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99142324; called by muse, mutect2, varscan2
- WRAP73 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99573489; called by muse, mutect2, varscan2
- DNAH11 | c.8088del p.L2698Yfs*13 | Frame Shift Del (DEL) | VAF 31/111 reads (28%) | called by mutect2, pindel, varscan2
- PHLDB1 | c.2773_2786del p.Q925Afs*73 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | called by mutect2, pindel, varscan2
- SLK | c.2440del p.T814Qfs*21 | Frame Shift Del (DEL) | VAF 30/64 reads (47%) | called by mutect2, pindel*, varscan2
- C16orf78 | c.774C>T p.T258= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs369429905, COSV100147928; called by muse, mutect2, varscan2
- GEM | c.291T>C p.G97= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV99891581; called by muse, mutect2, varscan2
- MDM2 | c.252A>C p.S84= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV99254860; called by muse, mutect2, varscan2
- NIBAN1 | c.1197T>C p.L399= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100836571; called by muse, mutect2, varscan2
